Somatic mutation profile of tumor specimen TCGA-BC-A10Y-01A (aliquot TCGA-BC-A10Y-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3; Age at diagnosis: 76.8 years (28,049 days).
Specimen TCGA-BC-A10Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f7e27c-46d8-43cc-a236-96b11ff6b114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10Y-11A (Solid Tissue Normal), aliquot TCGA-BC-A10Y-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c43c23ed-e989-4bac-8c26-17f5530c8aba

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 3, Splice Region 2, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC127029.3 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 147/545 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1379934275, CM095360, COSV60110898; called by muse, mutect2, varscan2
- ADGRB2 | c.3884T>A p.F1295Y | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.463); catalogued as COSV57073569; called by muse, mutect2, varscan2
- AFF2 | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 265/284 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV60664781; called by muse, mutect2, varscan2
- APBA2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as COSV68791170; called by muse, mutect2, varscan2
- ATP2C2 | c.1900A>T p.K634* | Nonsense Mutation (SNP) | VAF 47/107 reads (44%) | catalogued as COSV52295906; called by muse, mutect2, varscan2
- ATP5F1B | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV51636564; called by muse, mutect2, varscan2
- ATP8A2 | c.1844A>G p.H615R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1277027012, COSV54937093, COSV54951351; called by muse, mutect2, varscan2
- COL16A1 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV54705594; called by muse, mutect2, varscan2
- CRPPA | c.1042T>A p.F348I (on ENST00000407010 / NM_001368197.1; = p.F298I on NM_001101417.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs199890239, COSV67905915; called by muse, mutect2, varscan2
- CXCR6 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763564057, COSV56115872; called by muse, mutect2, varscan2
- DCLK1 | c.1635C>A p.Y545* | Nonsense Mutation (SNP) | VAF 100/227 reads (44%) | catalogued as COSV55173080; called by muse, mutect2, varscan2
- DPP10 | c.977G>T p.W326L | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59685490; called by muse, mutect2, varscan2
- ECH1 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55489200; called by muse, mutect2, varscan2
- EIF2S3 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 307/344 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53406661; called by muse, mutect2, varscan2
- EPHB2 | c.2955+7C>T | Splice Region (SNP) | VAF 38/66 reads (58%) | catalogued as COSV101007033; called by muse, mutect2, varscan2
- G6PC | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV53830962; called by muse, mutect2, varscan2
- GDF5 | c.713A>T p.E238V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65501541; called by muse, mutect2
- GPHN | c.2052A>T p.E684D (on ENST00000315266 / NM_001377519.1; = p.E717D on NM_020806.5) | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV59480170; called by muse, mutect2, varscan2
- ICAM1 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53424967; called by muse, mutect2, varscan2
- LAMB4 | c.4321A>G p.N1441D | Missense Mutation (SNP) | VAF 152/330 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV52718827, COSV52720213; called by muse, mutect2, varscan2
- LHX8 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1164496745, COSV53956648; called by muse, mutect2, varscan2
- MAP3K15 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs760272533, COSV58830017; called by muse, mutect2, varscan2
- MAZ | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1472297609, COSV50715017; called by muse, mutect2, varscan2
- METTL9 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1378611022, COSV63961709; called by muse, mutect2, varscan2
- NIPAL4 | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV57429903; called by muse, mutect2, varscan2
- OR1J2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV58944378; called by muse, mutect2, varscan2
- OR4M1 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 260/583 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1333211973, COSV60061300; called by muse, mutect2, varscan2
- PCLO | c.14240A>G p.Q4747R | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61634693; called by muse, mutect2, varscan2
- PLCXD2 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67339875; called by muse, mutect2, varscan2
- POGZ | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV55035569; called by muse, mutect2, varscan2
- REXO5 | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV54471978; called by muse, mutect2, varscan2
- RHO | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs753609310, COSV56213500; called by muse, mutect2, varscan2
- RRBP1 | c.4004C>T p.A1335V (on ENST00000377813 / NM_001365613.2; = p.A902V on NM_004587.3) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV55699933; called by muse, mutect2, varscan2
- RRP1B | c.216A>G p.E72= | Splice Region (SNP) | VAF 54/117 reads (46%) | catalogued as COSV61479056; called by muse, mutect2, varscan2
- SEMA7A | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753166445, COSV56089678; called by muse, mutect2, varscan2
- SERPINB6 | c.58A>G p.M20V (on ENST00000612421 / NM_001271823.2; = p.M1? on NM_004568.6) | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770912151, COSV59565696; called by muse, mutect2, varscan2
- SNTG2 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV57982427; called by muse, mutect2, varscan2
- ST8SIA2 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 24/82 reads (29%) | PolyPhen possibly damaging (0.715); catalogued as rs149476731, COSV51567035; called by muse, mutect2, varscan2
- UGT2B15 | c.670T>C p.W224R | Missense Mutation (SNP) | VAF 134/167 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57734415; called by muse, mutect2, varscan2
- ULK2 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64445711; called by muse, mutect2, varscan2
- UPK1B | c.297T>A p.Y99* | Nonsense Mutation (SNP) | VAF 163/400 reads (41%) | catalogued as COSV51767077; called by muse, mutect2, varscan2
- USH2A | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as COSV56333800, COSV56367952; called by muse, mutect2, varscan2
- VRK2 | c.1164G>C p.M388I | Missense Mutation (SNP) | VAF 131/318 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60876597, COSV60876785; called by muse, mutect2, varscan2
- XG | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 176/192 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV101150852; called by muse, mutect2, varscan2
- YTHDF3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72773477; called by muse, mutect2, varscan2
- ZNF445 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV68538844; called by muse, mutect2, varscan2
- ACSBG1 | c.1254-14_1261del p.X418_splice | Splice Site (DEL) | VAF 25/146 reads (17%) | called by mutect2, pindel, varscan2
- ZNF785 | c.741del p.R247Sfs*183 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.3402G>A p.L1134= | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as rs1443375025, COSV52285723; called by muse, mutect2, varscan2
- CCDC88C | c.3432G>A p.T1144= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as rs1179685333, COSV66237856; called by muse, mutect2, varscan2
- COTL1 | c.273C>T p.R91= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as rs376530038, COSV52290258; called by muse, mutect2, varscan2
- CTNNA2 | c.321C>T p.S107= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs1422999639, COSV63566084; called by muse, mutect2, varscan2
- GPSM1 | c.1071G>A p.Q357= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV61304090; called by muse, mutect2, varscan2
- JMJD1C | c.5907C>T p.C1969= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV59514763; called by muse, mutect2, varscan2
- KHSRP | c.495A>G p.E165= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV67919252; called by muse, mutect2, varscan2
- KMT2C | c.8946T>G p.V2982= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as rs760077828, COSV51438494; called by muse, mutect2, varscan2
- MAN1B1 | c.1626C>T p.P542= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as rs754107444, COSV65371065, COSV65371322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRCAM | c.639C>T p.R213= (on ENST00000379028 / NM_001371124.1; = p.R207= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs758654630, COSV61036603; called by muse, mutect2, varscan2
- PCDH11Y | c.414C>T p.C138= (on ENST00000400457 / NM_032973.2; = p.C127= on NM_032971.3) | Silent (SNP) | VAF 410/508 reads (81%) | catalogued as COSV53080651; called by muse, mutect2, varscan2
- PDGFA | c.321G>A p.R107= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV63279647; called by muse, mutect2, varscan2
- POLE2 | c.375T>C p.D125= | Silent (SNP) | VAF 71/154 reads (46%) | catalogued as COSV53559738; called by muse, mutect2, varscan2
- PTCH1 | c.339G>T p.A113= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as COSV59473740; called by muse, mutect2, varscan2
- RABL6 | c.1089G>A p.G363= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV61035565; called by muse, mutect2, varscan2
- SLIT3 | c.3159C>T p.P1053= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs1381899386, COSV60607688; called by muse, mutect2
- TRPM6 | c.1923G>A p.A641= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as rs372508531; called by muse, mutect2, varscan2
- ZHX2 | c.1515C>A p.S505= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV58713167; called by muse, mutect2, varscan2
- BPHL | c.107+652T>A | Intron (SNP) | VAF 58/186 reads (31%) | catalogued as rs374716930; called by muse, mutect2, varscan2
